Gene-level copy-number profile of tumor specimen TCGA-MQ-A6BR-01A from TCGA case TCGA-MQ-A6BR, project TCGA-MESO (Mesothelioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 55.1 years (20,134 days).
Specimen TCGA-MQ-A6BR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-MESO.a2d30ef5-82e7-4326-91c9-9e4beacc2940.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MQ-A6BR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1b650418-2a34-4dcd-aec7-680199613653

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 2,655; copy number 2: 51,759; copy number 3: 2,007; copy number 4: 3,383.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MQ-A6BR-01A-11D-A34B-01): tumor purity 0.62, ploidy 2.1, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:6,573,767–6,577,359, 1 gene: AC007223.1.
- chr16:7,301,605–7,431,296, 2 genes: AC007222.2, AC007222.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,655. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
